MMRF case MMRF_1296 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/9a2b0af5-bcf5-4398-bcd0-d4f4c7cc9852

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 81 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 81.5 years (29,765 days); ISS stage: I; Days to last known disease status: 506 days (1.4 years); Days to last follow up: 506 days (1.4 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 267 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.432 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 27.6 mg/dL; Immunoglobulin G 6.51 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 1.9 µg/mL; Lactate Dehydrogenase 4.27 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.15 mmol/L; Albumin 39 g/L; Total Protein 5.7 g/dL; Glucose 4.07 mmol/L.
- Day 79 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.924 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.46 mg/dL; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 128 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.15 mmol/L; Albumin 38 g/L; Total Protein 5.8 g/dL; Glucose 6 mmol/L.
- Day 170 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.991 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.82 mg/dL; Immunoglobulin G 8.11 g/L; Immunoglobulin A 1.72 g/L; Immunoglobulin M 0.47 g/L; Beta 2 Microglobulin 0.7 µg/mL; Lactate Dehydrogenase 7.22 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.15 mmol/L; Albumin 39 g/L; Total Protein 6.8 g/dL; Glucose 4.84 mmol/L.
- Day 254 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.32 mg/dL; Immunoglobulin G 10 g/L; Immunoglobulin A 1.57 g/L; Immunoglobulin M 0.45 g/L; Beta 2 Microglobulin 2 µg/mL; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 263 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.2 mmol/L; Albumin 34 g/L; Total Protein 6.4 g/dL; Glucose 5.89 mmol/L.
- Day 338 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.849 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.49 mg/dL; Immunoglobulin G 9.7 g/L; Immunoglobulin A 1 g/L; Immunoglobulin M 0.4 g/L; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 6.27 mmol/L.
- Day 422 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.746 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 17.1 mg/dL; Immunoglobulin G 8.99 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.2 mmol/L; Albumin 41 g/L; Total Protein 6.2 g/dL; Glucose 6.33 mmol/L.
- Day 506 (ECOG 0): M Protein 6.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.153 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 36.2 mg/dL; Immunoglobulin G 7.14 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 3.33 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 45 g/L; Total Protein 6.8 g/dL; Glucose 4.35 mmol/L.

Other clinical attributes
- Day -3: Weight: 59 kg; Height: 165 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Bladder Cancer.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Breast Cancer.
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (1 sample)
- Sample MMRF_1296_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -3 days.
